Somatic mutation profile of tumor specimen TCGA-BR-4357-01A (aliquot TCGA-BR-4357-01A-01D-1158-08) from TCGA case TCGA-BR-4357, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; Tumor grade: G2; Age at diagnosis: 58.3 years (21,295 days).
Specimen TCGA-BR-4357-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fc0ca29-6ad9-4979-8f5c-0e603c3ee702.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4357-11A (Solid Tissue Normal), aliquot TCGA-BR-4357-11A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/401b6c74-59d1-453a-8a7b-0bb06b845fb3

The open-access MAF lists 247 somatic variants for this specimen: 186 protein-altering or splice-affecting, 54 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 54, Nonsense Mutation 6, Frame Shift Del 4, Intron 4, Frame Shift Ins 2, RNA 2, 3'UTR 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 89/135 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as rs187784898, COSV57056330; called by muse, mutect2, varscan2
- ABCA8 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV52206326; called by muse, mutect2, varscan2
- ABCC4 | c.682C>A p.L228I | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV65315158; called by muse, mutect2, varscan2
- ABCC9 | c.4283A>T p.K1428M | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53978016; called by muse, mutect2, varscan2
- ABCC9 | c.3805T>A p.L1269M | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV53978035, COSV99687670; called by muse, mutect2, varscan2
- ABT1 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.778); catalogued as rs782771069, COSV51291961; called by muse, mutect2, varscan2
- ADAP2 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 88/439 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as COSV58296513; called by muse, mutect2, varscan2
- AGPAT4 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV57247978; called by muse, mutect2, varscan2
- AGXT2 | c.1516A>C p.T506P | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV51488182; called by muse, mutect2, varscan2
- AGXT2 | c.572T>A p.I191N | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51488199; called by muse, mutect2, varscan2
- AJAP1 | c.749T>G p.V250G | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV65451938; called by muse, mutect2, varscan2
- AL031777.2 | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61911807, COSV61912140; called by muse, mutect2, varscan2
- ASH1L | c.3904C>T p.R1302W | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs746450493, COSV64210433; called by muse, mutect2, varscan2
- AUTS2 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV61390323; called by muse, mutect2, varscan2
- B4GALT2 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386088844, COSV58844713; called by muse, mutect2, varscan2
- BLZF1 | c.681T>A p.D227E | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as COSV61394242; called by muse, mutect2, varscan2
- BRINP3 | c.1951T>G p.F651V | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV66531196; called by muse, mutect2, varscan2
- BTNL9 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 88/157 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV59797199; called by muse, mutect2, varscan2
- CACNA1A | c.5037G>C p.Q1679H | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV64203911; called by muse, mutect2
- CACNA1C | c.527T>A p.L176* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV59742163; called by mutect2, varscan2
- CASZ1 | c.2167G>T p.D723Y | Missense Mutation (SNP) | VAF 153/444 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59738343; called by muse, mutect2, varscan2
- CAT | c.863A>G p.Q288R | Missense Mutation (SNP) | VAF 30/527 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV53812048; called by muse, mutect2
- CCER1 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV62647658; called by muse, mutect2, varscan2
- CDC5L | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 126/242 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.115); catalogued as COSV65175107, COSV65177679; called by muse, mutect2, varscan2
- CEACAM18 | c.778T>G p.F260V | Missense Mutation (SNP) | VAF 85/354 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV67282217; called by muse, mutect2, varscan2
- CELA3A | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 71/686 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV51584999; called by muse, mutect2, varscan2
- CELSR3 | c.2713C>T p.R905C | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs755186680, COSV50912620; called by muse, mutect2, varscan2
- CEMIP | c.631A>G p.R211G | Missense Mutation (SNP) | VAF 116/252 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV54996039; called by muse, mutect2, varscan2
- CHI3L2 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV63874361; called by muse, mutect2, varscan2
- CLCF1 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV56862002; called by muse, mutect2, varscan2
- COL27A1 | c.750C>A p.F250L | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV61928370; called by muse, mutect2, varscan2
- COX18 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs763271464, COSV55720888; called by muse, mutect2, varscan2
- CXCR1 | c.932A>C p.N311T | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV55282372; called by muse, mutect2
- DDB1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57103853; called by muse, varscan2
- DEFB106B | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100128912; called by mutect2, varscan2
- DLC1 | c.1913G>A p.G638D (on ENST00000276297 / NM_001348081.2; = p.G201D on NM_006094.5) | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1355922344, COSV52314441, COSV99362876; called by muse, mutect2, varscan2
- DLC1 | c.1770G>T p.E590D (on ENST00000276297 / NM_001348081.2; = p.E153D on NM_006094.5) | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV52314452; called by muse, mutect2, varscan2
- DLG5 | c.4935G>C p.K1645N | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV64948740; called by muse, mutect2, varscan2
- DMD | c.4169A>T p.D1390V | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63771900; called by muse, mutect2, varscan2
- DNAH5 | c.13265T>C p.I4422T | Missense Mutation (SNP) | VAF 189/438 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763286954, COSV54237945; called by muse, mutect2, varscan2
- DNAH8 | c.7285T>G p.L2429V | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59462569; called by muse, mutect2
- DRD5 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs534674002, COSV99079689; called by muse, mutect2, varscan2
- DST | c.15838A>G p.I5280V (on ENST00000361203 / NM_001374722.1; = p.I2868V on NM_015548.5) | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs754589018, COSV55025702; called by muse, mutect2, varscan2
- DYNC2H1 | c.3988A>G p.R1330G | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62099512; called by muse, mutect2, varscan2
- EFR3A | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV54459558; called by muse, mutect2, varscan2
- EHMT1 | c.3418G>A p.V1140M | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770731320, COSV71777963; called by muse, mutect2, varscan2
- EIF2S1 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as COSV53600017; called by muse, mutect2, varscan2
- EIF4G2 | c.1749C>G p.S583R | Missense Mutation (SNP) | VAF 75/326 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.983); catalogued as rs1188893518, COSV60598169; called by muse, mutect2, varscan2
- ENO1 | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.933); catalogued as COSV52304634; called by muse, mutect2
- EXT2 | c.971C>A p.A324D (on ENST00000343631; = p.A357D on NM_000401.3) | Missense Mutation (SNP) | VAF 86/343 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.78); catalogued as COSV59152329; called by muse, mutect2, varscan2
- FAM135A | c.335C>T p.S112F (on ENST00000370479 / NM_001351599.1; = p.S69F on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.908); catalogued as COSV52054814; called by muse, mutect2, varscan2
- FAM234B | c.1271T>G p.L424R | Missense Mutation (SNP) | VAF 73/304 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.387); catalogued as COSV52195810; called by muse, mutect2, varscan2
- FANCB | c.2055C>G p.I685M | Missense Mutation (SNP) | VAF 74/121 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.803); catalogued as COSV60760851; called by muse, mutect2, varscan2
- FBN2 | c.7862A>C p.N2621T | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.396); catalogued as COSV52527420; called by muse, mutect2, varscan2
- FMNL1 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58957848; called by muse, mutect2
- FNIP2 | c.3323A>T p.Y1108F | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV52437409; called by muse, mutect2
- FOXRED1 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766922221, COSV55007715; called by muse, mutect2, varscan2
- FTMT | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV58420822; called by muse, mutect2
- GABRB3 | c.1142T>A p.V381D | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV54672792; called by muse, mutect2, varscan2
- GPATCH4 | c.322A>C p.N108H | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV58040723; called by muse, mutect2
- GPR61 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1315166781, COSV68177849; called by muse, mutect2, varscan2
- HUWE1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53354372; called by muse, mutect2, varscan2
- IL7R | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 97/329 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57410551; called by muse, mutect2, varscan2
- ITPRID1 | c.382A>C p.S128R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV60070325, COSV60077986; called by muse, mutect2, varscan2
- JAML | c.831C>G p.I277M (on ENST00000356289 / NM_001098526.2; = p.I267M on NM_153206.3) | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52627727, COSV52628463; called by muse, mutect2
- JPH2 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV65904518; called by muse, mutect2, varscan2
- KCNQ2 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 102/134 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568925719, COSV60432369; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNV2 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.204); catalogued as COSV66056847; called by muse, varscan2
- KRT18 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV66316383; called by muse, mutect2
- KRT72 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs774725571, COSV53375192; called by muse, mutect2, varscan2
- LAMA4 | c.4609C>T p.H1537Y (on ENST00000230538 / NM_001105206.3; = p.H1530Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV57895285, COSV57900806; called by muse, mutect2
- LARS1 | c.1472A>G p.K491R (on ENST00000394434 / NM_020117.11; = p.K464R on NM_016460.3) | Missense Mutation (SNP) | VAF 154/343 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV50980475; called by muse, varscan2
- LBR | c.1410C>G p.F470L | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55290278; called by muse, mutect2, varscan2
- LCE3D | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.367); catalogued as rs771339179, COSV64230967; called by muse, mutect2, varscan2
- LDHD | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV55581422; called by muse, mutect2
- LHCGR | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV54299655; called by muse, varscan2
- LMO7 | c.4168A>G p.K1390E (on ENST00000357063; = p.K1071E on NM_005358.5) | Missense Mutation (SNP) | VAF 87/273 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV58541618; called by muse, mutect2, varscan2
- LRBA | c.997T>G p.F333V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV63959253; called by muse, mutect2, varscan2
- LY75 | c.2819A>C p.K940T | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.739); catalogued as COSV55109270; called by muse, mutect2, varscan2
- MAML1 | c.1276C>A p.Q426K | Missense Mutation (SNP) | VAF 39/339 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV52987120; called by muse, mutect2, varscan2
- MAPT | c.1097G>A p.R366Q (on ENST00000262410 / NM_001377265.1; = p.R291Q on NM_016835.4) | Missense Mutation (SNP) | VAF 95/161 reads (59%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.005); catalogued as rs986022436, COSV52243191, COSV52243253; called by muse, mutect2, varscan2
- ME3 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV62773744; called by muse, mutect2, varscan2
- MFSD13A | c.567C>G p.F189L | Missense Mutation (SNP) | VAF 65/281 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as COSV53268208; called by muse, mutect2, varscan2
- MINPP1 | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.372); catalogued as COSV64354672; called by muse, mutect2, varscan2
- MPDZ | c.1155A>C p.Q385H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV59947262; called by muse, mutect2, varscan2
- MRC1 | c.4009G>A p.A1337T | Missense Mutation (SNP) | VAF 84/588 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as COSV53470637; called by muse, mutect2, varscan2
- MYO16 | c.3369G>A p.W1123* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100695461; called by muse, mutect2, varscan2
- MYO16 | c.3370C>G p.Q1124E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100696537; called by muse, mutect2, varscan2
- NAT10 | c.2291T>C p.L764P | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57665021; called by muse, mutect2
- NCOA6 | c.3748G>T p.G1250* | Nonsense Mutation (SNP) | VAF 20/492 reads (4%) | catalogued as COSV62865585; called by muse, mutect2
- NF1 | c.5674T>G p.L1892V (on ENST00000358273 / NM_001042492.3; = p.L1871V on NM_000267.3) | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62210300; called by muse, mutect2, varscan2
- NME8 | c.1665G>T p.Q555H | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs1470310487, COSV52252741; called by muse, mutect2, varscan2
- NOTCH4 | c.4036C>T p.R1346W | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs911402506, COSV66680932, COSV66682188; called by muse, mutect2
- NOX3 | c.934_935insC p.K312Tfs*5 | Frame Shift Ins (INS) | VAF 52/306 reads (17%) | catalogued as COSV99342984; called by pindel, varscan2
- NRK | c.680A>G p.D227G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54601115; called by muse, mutect2, varscan2
- NRK | c.4402T>A p.L1468M | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV54596640, COSV54601134; called by muse, mutect2, varscan2
- OLFML2B | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.683); catalogued as COSV54198049, COSV54198848; called by muse, mutect2, varscan2
- OR10A2 | c.180C>G p.F60L | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100225009, COSV56299880; called by muse, mutect2, varscan2
- OR13C2 | c.33A>T p.E11D | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV73377747; called by muse, mutect2, varscan2
- OR2T6 | c.145A>T p.I49F | Missense Mutation (SNP) | VAF 8/211 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63216714; called by muse, mutect2
- OR4E2 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 111/479 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778301649, COSV57731984; called by muse, mutect2, varscan2
- PAPPA2 | c.2503C>T p.Q835* | Nonsense Mutation (SNP) | VAF 80/401 reads (20%) | catalogued as COSV62781699; called by muse, mutect2, varscan2
- PARP14 | c.3169G>C p.E1057Q | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV71735109; called by muse, mutect2, varscan2
- PAX3 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.217); catalogued as rs549206921, COSV60590094; called by muse, mutect2
- PCNX3 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as COSV58420707; called by muse, varscan2
- PCNX3 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58420714; called by muse, varscan2
- PDZRN4 | c.1048C>T p.R350C (on ENST00000402685 / NM_001164595.2; = p.R92C on NM_013377.4) | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1379664518, COSV54208093; called by muse, mutect2
- PER2 | c.932T>G p.L311R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1265113062, COSV54525539, COSV54526122; called by muse, mutect2, varscan2
- PER3 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 51/345 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV62706776; called by muse, mutect2, varscan2
- PGAP3 | c.508T>C p.F170L | Missense Mutation (SNP) | VAF 48/805 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV54093457, COSV99510545; called by muse, mutect2
- PHF12 | c.2679C>T p.I893= | Splice Region (SNP) | VAF 43/180 reads (24%) | catalogued as COSV60455921; called by muse, mutect2, varscan2
- PIAS2 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.391); catalogued as COSV61344118; called by muse, mutect2, varscan2
- PID1 | c.367A>G p.T123A (on ENST00000354069 / NM_001330156.1; = p.T121A on NM_017933.5) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV62478596; called by muse, mutect2
- PLCB4 | c.3471G>A p.M1157I (on ENST00000278655 / NM_182797.3; = p.A1170T on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV53808376; called by muse, mutect2, varscan2
- PLEC | c.11271C>G p.I3757M (on ENST00000322810 / NM_201380.4; = p.I3647M on NM_000445.5) | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV59659202; called by muse, varscan2
- PLEC | c.11068G>C p.E3690Q (on ENST00000322810 / NM_201380.4; = p.E3580Q on NM_000445.5) | Missense Mutation (SNP) | VAF 35/687 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV59659269; called by muse, mutect2
- PLOD3 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV56184053; called by muse, mutect2, varscan2
- POP1 | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 56/341 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV62893451; called by muse, mutect2, varscan2
- PPOX | c.1258C>A p.P420T | Missense Mutation (SNP) | VAF 79/382 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60527546; called by muse, mutect2, varscan2
- PRDM14 | c.281G>A p.W94* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV52572684; called by muse, mutect2
- PRKAR2B | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55922733, COSV55926098; called by muse, mutect2, varscan2
- PRR23B | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 161/279 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.234); catalogued as COSV61494310; called by muse, mutect2, varscan2
- PTPRE | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV54554585; called by muse, mutect2, varscan2
- PTPRT | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV61997669; called by muse, mutect2
- PVR | c.1184A>T p.H395L | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.079); catalogued as COSV51823797; called by muse, mutect2
- PXK | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.408); catalogued as COSV57090849; called by muse, mutect2, varscan2
- RAB13 | c.29A>C p.K10T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100884089, COSV100884092; called by muse, mutect2, varscan2
- RALGAPB | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.983); catalogued as COSV53440554; called by muse, mutect2, varscan2
- REG1A | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV52070441; called by muse, mutect2, varscan2
- RNH1 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746459533, COSV62251071; called by muse, mutect2, varscan2
- ROBO2 | c.3292G>T p.G1098C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV59923144; called by muse, mutect2, varscan2
- RUNX1T1 | c.741-1G>A p.X247_splice (on ENST00000265814 / NM_001198628.1; = p.X220_splice on NM_004349.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 32/106 reads (30%) | catalogued as COSV56154232; called by muse, mutect2, varscan2
- RUNX1T1 | c.523T>G p.F175V (on ENST00000265814 / NM_001198628.1; = p.F148V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56148000; called by muse, mutect2, varscan2
- RYR3 | c.8585T>C p.L2862P (on ENST00000389232; = p.L2863P on NM_001036.6) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66799628; called by muse, mutect2, varscan2
- SCN5A | c.4499A>C p.K1500T (on ENST00000333535 / NM_198056.3; = p.K1499T on NM_000335.5) | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61121873; called by muse, mutect2
- SEMA3B | c.902A>G p.D301G | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60351925; called by muse, mutect2, varscan2
- SEMA5A | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 86/423 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs868269067, COSV66799175; called by muse, mutect2, varscan2
- SEMG2 | c.726T>A p.H242Q | Missense Mutation (SNP) | VAF 241/529 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV65647688; called by muse, mutect2, varscan2
- SIDT1 | c.1320_1321insC p.Y441Lfs*2 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | catalogued as COSV99333615; called by mutect2, pindel
- SLC22A10 | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); catalogued as COSV60422194; called by muse, mutect2, varscan2
- SLC34A2 | c.1900G>C p.D634H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV101158278; called by muse, mutect2, varscan2
- SLC35B4 | c.127A>T p.I43F | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65985038; called by muse, mutect2
- SLC35G2 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 107/447 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV67588634; called by muse, mutect2, varscan2
- SLC38A4 | c.1009C>G p.P337A | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56969060, COSV56971450; called by muse, mutect2, varscan2
- SLC39A12 | c.942G>T p.R314S | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV66198569, COSV66200422; called by muse, mutect2, varscan2
- SLC66A2 | c.606G>C p.M202I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV60843907; called by muse, mutect2, varscan2
- SPACA7 | c.80G>T p.R27I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV52100760, COSV52101504; called by muse, mutect2, varscan2
- SPRY3 | c.859T>A p.S287T | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV57143618; called by muse, mutect2, varscan2
- SPTA1 | c.6265T>A p.L2089M | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.103); catalogued as COSV100935860, COSV63756377; called by muse, mutect2, varscan2
- STARD13 | c.2004C>G p.H668Q (on ENST00000336934 / NM_001243476.3; = p.H550Q on NM_052851.3) | Missense Mutation (SNP) | VAF 119/324 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV55233421; called by muse, mutect2, varscan2
- STEAP1 | c.279A>C p.E93D | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765303046, COSV51882224; called by muse, mutect2
- STK32B | c.973C>A p.L325I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV51478356, COSV51498771; called by muse, mutect2, varscan2
- TCERG1 | c.1808C>G p.S603C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV57039204; called by muse, mutect2, varscan2
- TIMP3 | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56663385, COSV56665358; called by muse, mutect2, varscan2
- TMC2 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 122/347 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV62655496; called by muse, mutect2, varscan2
- TMEM106C | c.689T>A p.M230K | Missense Mutation (SNP) | VAF 63/462 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV56743088; called by mutect2, varscan2
- TNS3 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759568949, COSV100235116; called by muse, mutect2, varscan2
- TRMT2B | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as rs751813401, COSV58620262; called by muse, mutect2, varscan2
- TRUB1 | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 87/309 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as COSV53930370; called by muse, mutect2, varscan2
- TTBK2 | c.2176A>G p.S726G | Missense Mutation (SNP) | VAF 14/303 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV51167463, COSV51169539; called by muse, mutect2
- TTF1 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV57505697; called by muse, mutect2, varscan2
- TTN | c.94242C>A p.D31414E (on ENST00000591111; = p.D23990E on NM_003319.4) | Missense Mutation (SNP) | VAF 91/486 reads (19%) | PolyPhen benign (0.274); catalogued as COSV60181221; called by muse, mutect2, varscan2
- TTN | c.70804G>C p.E23602Q (on ENST00000591111; = p.E16178Q on NM_003319.4) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | PolyPhen probably damaging (0.997); catalogued as rs1114167338, COSV60181251; called by muse, mutect2, varscan2
- TTN | c.25763A>C p.Q8588P (on ENST00000591111; = p.Q7661P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | PolyPhen benign (0.439); catalogued as COSV60181294; called by muse, varscan2
- UFSP2 | c.616A>T p.K206* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | catalogued as COSV52990649, COSV52991685, COSV52992198; called by muse, mutect2, varscan2
- UNC79 | c.3187G>A p.A1063T (on ENST00000393151 / NM_001346218.2; = p.A886T on NM_020818.5) | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV56397448, COSV56399965; called by muse, mutect2, varscan2
- WWC3 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 163/271 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs762106268, COSV66505003; called by muse, mutect2, varscan2
- XIRP2 | c.6804A>C p.K2268N (on ENST00000628543; = p.K2443N on NM_152381.6) | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); catalogued as COSV54704229; called by muse, mutect2, varscan2
- XRN1 | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV53814670; called by muse, mutect2, varscan2
- YWHAZ | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.943); catalogued as COSV62054507; called by muse, mutect2, varscan2
- ZC3H13 | c.3782G>A p.R1261Q | Missense Mutation (SNP) | VAF 70/361 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs375011338; called by muse, mutect2, varscan2
- ZDHHC6 | c.41A>G p.Q14R | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV65564813; called by muse, mutect2, varscan2
- ZEB2 | c.1432T>G p.C478G | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.111); catalogued as COSV57960837, COSV57964484; called by muse, mutect2, varscan2
- ZNF107 | c.1300C>A p.H434N | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV61328721, COSV61330052; called by muse, mutect2
- ZNF479 | c.631A>C p.K211Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV100482665; called by muse, mutect2, varscan2
- ZNF479 | c.630G>T p.E210D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as rs1554400342, COSV100482666, COSV58638869; called by muse, mutect2, varscan2
- ZNF804A | c.772C>A p.H258N | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100166040, COSV56458123; called by muse, mutect2, varscan2
- ZNF804B | c.2006A>T p.H669L | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.057); catalogued as COSV60838650; called by muse, mutect2, varscan2
- CCL18 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CPNE8 | c.1565G>C p.R522T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MRC1 | c.1978T>G p.F660V | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RABL6 | c.1863_1873del p.K622Gfs*17 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | called by mutect2, pindel, varscan2
- RFC1 | c.312_316del p.T105Hfs*6 | Frame Shift Del (DEL) | VAF 21/135 reads (16%) | called by mutect2, pindel, varscan2
- SYCP1 | c.865_871del p.L289Nfs*9 | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | called by mutect2, pindel, varscan2
- ZNF284 | c.1358_1359del p.R453Tfs*3 | Frame Shift Del (DEL) | VAF 61/204 reads (30%) | called by pindel, varscan2
- ABCB4 | c.3351T>C p.A1117= (on ENST00000265723 / NM_018849.3; = p.A1110= on NM_000443.4) | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV55938063; called by muse, mutect2, varscan2
- ADAMTSL3 | c.552T>G p.T184= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV54457241; called by muse, mutect2, varscan2
- ADCY2 | c.1284T>C p.S428= | Silent (SNP) | VAF 90/285 reads (32%) | catalogued as COSV57884047; called by muse, mutect2, varscan2
- AHSG | c.441A>G p.Q147= | Silent (SNP) | VAF 24/194 reads (12%) | catalogued as COSV56608409; called by muse, mutect2, varscan2
- BARD1 | c.2025C>T p.C675= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV53614096; called by muse, mutect2, varscan2
- CLEC16A | c.1320C>T p.I440= | Silent (SNP) | VAF 21/183 reads (11%) | catalogued as COSV68500680; called by muse, varscan2
- CNTN1 | c.1368C>G p.V456= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV61637889, COSV61642237, COSV61645910; called by muse, mutect2
- CRYBG1 | c.4789T>C p.L1597= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as COSV64813174; called by muse, mutect2
- CSMD3 | c.4615C>A p.R1539= (on ENST00000297405 / NM_001363185.1; = p.R1435= on NM_052900.3) | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as COSV52239671; called by muse, mutect2, varscan2
- DHRS9 | c.204T>C p.A68= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as COSV59140711; called by muse, mutect2
- DMXL1 | c.3207A>G p.R1069= | Silent (SNP) | VAF 180/378 reads (48%) | catalogued as COSV60716173; called by muse, mutect2, varscan2
- DNAJC11 | c.711G>A p.V237= | Silent (SNP) | VAF 84/375 reads (22%) | catalogued as COSV53788433; called by muse, mutect2, varscan2
- ELP5 | c.585C>A p.G195= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV63039698; called by muse, mutect2, varscan2
- FBXL7 | c.990C>T p.S330= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV61642958; called by muse, mutect2
- HECW1 | c.936C>T p.H312= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs777512794, COSV67834530; called by muse, mutect2, varscan2
- HSPA5 | c.1779C>G p.T593= | Silent (SNP) | VAF 44/330 reads (13%) | catalogued as COSV52336772; called by muse, mutect2, varscan2
- IFFO1 | c.1029G>T p.V343= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV60738412; called by muse, mutect2, varscan2
- KDM3A | c.114C>T p.V38= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV57223300; called by muse, mutect2, varscan2
- KIRREL3 | c.222C>T p.Y74= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs745333764, COSV73105087; ClinVar: likely benign; called by muse, mutect2, varscan2
- LIG3 | c.2904G>A p.Q968= | Silent (SNP) | VAF 65/134 reads (49%) | catalogued as COSV52006276, COSV52009134; called by muse, mutect2, varscan2
- MED1 | c.4179C>T p.I1393= | Silent (SNP) | VAF 48/486 reads (10%) | catalogued as COSV56126791; called by muse, mutect2
- MPO | c.1599C>T p.A533= | Silent (SNP) | VAF 57/319 reads (18%) | catalogued as rs779934310, COSV51860482; called by muse, mutect2, varscan2
- MUC16 | c.10794T>C p.T3598= | Silent (SNP) | VAF 50/182 reads (27%) | catalogued as COSV67478427; called by muse, mutect2, varscan2
- NANOG | c.210C>G p.T70= | Silent (SNP) | VAF 14/335 reads (4%) | catalogued as COSV57551977; called by muse, mutect2
- NIPBL | c.1656C>T p.D552= | Silent (SNP) | VAF 478/1000 reads (48%) | catalogued as COSV56957650; called by mutect2, varscan2
- OBI1 | c.1503G>A p.E501= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as rs1246248590, COSV56146326; called by muse, mutect2
- OR2T3 | c.801G>A p.P267= | Silent (SNP) | VAF 54/962 reads (6%) | catalogued as rs370677701; called by muse, mutect2
- OR2T34 | c.801G>A p.R267= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs369573703, COSV100170337; called by muse, mutect2, varscan2
- OR4K1 | c.267C>A p.R89= | Silent (SNP) | VAF 33/230 reads (14%) | catalogued as COSV53461191; called by muse, varscan2
- OR5M10 | c.12A>G p.P4= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV73242373; called by muse, mutect2, varscan2
- PAK3 | c.882A>C p.S294= (on ENST00000262836 / NM_001324328.2; = p.S279= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 111/202 reads (55%) | catalogued as COSV53277335; called by muse, mutect2, varscan2
- PCDHA6 | c.1533C>T p.H511= | Silent (SNP) | VAF 98/217 reads (45%) | catalogued as rs781943283, COSV65345598, COSV65346836; called by muse, mutect2, varscan2
- PCDHGA4 | c.267G>A p.E89= | Silent (SNP) | VAF 17/164 reads (10%) | catalogued as COSV53983891; called by muse, mutect2, varscan2
- PCDHGB3 | c.2310A>C p.I770= | Silent (SNP) | VAF 46/84 reads (55%) | catalogued as COSV53983910; called by muse, mutect2, varscan2
- PDLIM3 | c.453C>T p.F151= (on ENST00000284770 / NM_001257963.1; = p.F318= on NM_014476.6) | Silent (SNP) | VAF 53/224 reads (24%) | catalogued as rs757507673, COSV52980144; called by muse, mutect2, varscan2
- PPP1R3C | c.664T>C p.L222= | Silent (SNP) | VAF 49/218 reads (22%) | catalogued as COSV53288713; called by muse, mutect2, varscan2
- PSG1 | c.846C>A p.V282= | Silent (SNP) | VAF 87/518 reads (17%) | catalogued as COSV99739539; called by muse, mutect2, varscan2
- PTGR1 | c.951G>C p.L317= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV53029816; called by muse, mutect2, varscan2
- RTL9 | c.3495G>A p.E1165= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV71825910; called by muse, mutect2, varscan2
- SEMA6D | c.1947A>G p.E649= (on ENST00000316364 / NM_153618.2; = p.E587= on NM_020858.2) | Silent (SNP) | VAF 55/221 reads (25%) | catalogued as COSV60371874, COSV60373482, COSV60380284; called by muse, mutect2, varscan2
- SLC22A25 | c.1104T>G p.T368= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100123554; called by muse, mutect2
- SLIT1 | c.1818C>T p.S606= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs527636768, COSV56586847, COSV56593311; called by muse, mutect2, varscan2
- SMG9 | c.1479G>A p.K493= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as rs1350956906, COSV54215437; called by muse, mutect2, varscan2
- SPEN | c.8139C>A p.A2713= | Silent (SNP) | VAF 47/214 reads (22%) | catalogued as COSV65364551; called by muse, varscan2
- SUSD4 | c.639A>G p.G213= | Silent (SNP) | VAF 53/326 reads (16%) | catalogued as COSV59554477; called by muse, mutect2, varscan2
- SYNDIG1 | c.147G>A p.Q49= | Silent (SNP) | VAF 11/203 reads (5%) | catalogued as rs1223680029, COSV65237268; called by muse, mutect2
- TAF5 | c.1833C>G p.L611= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV58916012; called by muse, mutect2, varscan2
- TMEM65 | c.495G>T p.V165= | Silent (SNP) | VAF 21/218 reads (10%) | catalogued as COSV52631148; called by muse, mutect2
- TOX4 | c.858A>C p.A286= | Silent (SNP) | VAF 101/290 reads (35%) | catalogued as COSV52970072; called by muse, mutect2, varscan2
- TYR | c.462G>A p.G154= | Silent (SNP) | VAF 57/350 reads (16%) | catalogued as rs1565386665, COSV54471645, COSV54477038; called by muse, mutect2, varscan2
- UNC5C | c.2490G>A p.A830= | Silent (SNP) | VAF 30/447 reads (7%) | catalogued as rs762675647, COSV71658933; called by muse, mutect2
- VPS13D | c.10110A>G p.Q3370= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV50653843; called by muse, mutect2, varscan2
- WNK1 | c.4251A>G p.T1417= (on ENST00000315939 / NM_018979.4; = p.T1170= on NM_014823.3) | Silent (SNP) | VAF 31/366 reads (8%) | catalogued as rs766701999, COSV60038797; called by muse, mutect2
- ZGRF1 | c.1743T>C p.C581= | Silent (SNP) | VAF 52/200 reads (26%) | catalogued as COSV52201846; called by muse, mutect2, varscan2
- ADGRE4P | n.1238C>G | RNA (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- CCDC33 | c.1291-11575C>G | Intron (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99173241; called by muse, mutect2, varscan2
- DST | c.4297-4873T>C | Intron (SNP) | VAF 8/158 reads (5%) | catalogued as COSV99754163; called by muse, mutect2
- NCAPD2 | c.262+121A>C | Intron (SNP) | VAF 132/347 reads (38%) | catalogued as rs1255177923, COSV100217043; called by muse, mutect2, varscan2
- NPR3 | c.*3355T>G | 3'UTR (SNP) | VAF 47/215 reads (22%) | catalogued as COSV54086862; called by muse, mutect2, varscan2
- OR2U1P | n.641T>G | RNA (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2821T>A | Intron (SNP) | VAF 7/29 reads (24%) | catalogued as rs773804052, COSV57627386, COSV57627470; called by muse, mutect2, varscan2
